Gene-level copy-number profile of tumor specimen TCGA-Y6-A9XI-01A from TCGA case TCGA-Y6-A9XI, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 72.5 years (26,471 days).
Specimen TCGA-Y6-A9XI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.c3209e2a-b97c-46de-862d-3305c688944b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-Y6-A9XI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d9126fbb-a7f6-4e66-8290-6bc5860535fe

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 6,318; copy number 2: 53,440; copy number 3: 34; copy number 4: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-Y6-A9XI-01A-11D-A41J-01): tumor purity 0.83, ploidy 1.92, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:72,665,123–73,891,871, 20 genes: AC004943.2, RNU7-90P, KRT18P18, AC004943.3, ZFHX3, AC004943.1, RNU7-71P, AC132068.1, AC002044.3, AC002044.1, AC002044.2, AC116667.1, HCCAT5, AC116667.2, AC140912.1, AC009033.1, LINC01568, AC092114.1, AC087565.2, AC087565.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 3,937. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
